Gene-level copy-number profile of tumor specimen TCGA-YL-A8SO-01B from TCGA case TCGA-YL-A8SO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.6 years (23,584 days).
Specimen TCGA-YL-A8SO-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.e5d7a947-32e5-4be5-ba82-b0077531b7c3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-YL-A8SO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/26a88907-3a0b-423b-961d-6bc89ea06de4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 8,122; copy number 2: 46,124; copy number 3: 2,667; copy number 4: 2,889.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-YL-A8SO-01B-31D-A376-01): tumor purity 0.55, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:95,654,423–95,919,552, 2 genes: MTHFD2P1, AC106719.1.
- chr6:123,589,711–124,825,640, 3 genes (within-gene range 0–1): AL133257.1, NKAIN2, AL354936.1.
- chr7:127,346,790–127,431,924, 1 gene (within-gene range 0–3): ZNF800.
- chr7:127,359,785–127,364,759, 1 gene: AC000123.3.
- chr13:89,991,831–91,023,954, 10 genes: PEX12P1, LINC00559, RNA5SP34, FAR1P1, KRT18P27, MIR622, LINC01049, RNU6-75P, LINC00410, BRK1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 5,736. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
